CCDI case PBBUFR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/6621c61b-5015-483d-9312-f7903ca4d303

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.2 years (1,546 days).

Biospecimens (3 samples)
- Sample 0DH27K: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DH28S: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DH29L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
